Surgical pathology report (de-identified scan), TCGA case TCGA-56-8628, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-8628-01A (Primary Tumor).

[page 1 of 5]
FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

A. - F.) LUNG, RIGHT UPPER LOBE, LYMPH NODES, N10R, N10R#2, N11R, N4R, N7, LOBECTOMY AND REGIONAL LYMPH NODE RESECTIONS:

- Squamous cell carcinoma, poorly differentiated.
- Tumor size: 2.1 cm.
- No pleural extension identified.
- Surgical margins negative.
- Fourteen lymph nodes, no tumor seen (0/14).

PATHOLOGIC TUMOR STAGING SYNOPSIS (RIGHT UPPER LOBE LUNG):

Type and grade: Squamous cell carcinoma, poorly differentiated.

Primary tumor: pT1b.

Regional lymph nodes: pN0.

Distant metastasis: N/A.

Pathologic stage: IA.

Lymphovascular invasion: Not identified.

Margin status: R0, negative.

[page 2 of 5]
Procedure:	Right upper lobe lobectomy and regional lymph node resections.
Specimen type:	Right upper lobe and regional lymph node resections.
Specimen laterality:	Right.
Specimen integrity:	Intact.
Tumor Features:	
Tumor site:	Right upper lobe.
Tumor size:	2.1 cm.
Tumor focality:	Single focus.
Histologic type:	Squamous cell carcinoma.
Histologic grade:	G3, poorly differentiated.
Lymphovascular invasion:	Not identified.
Perineural invasion:	Not identified.
Visceral pleural invasion:	PL0, not identified.
Tumor extension into extra-pulmonary structures:	Not identified.
Treatment effect:	N/A.
Lymph Nodes:	Fourteen lymph nodes, no tumor seen.
Margin Evaluation:	
Distance to closest margin:	Parietal pleura at 0.8 cm.
Bronchial margin:	3 cm.
Vascular margin:	Greater than 3 cm.
Parenchymal margin:	Greater than 3 cm.
Parietal pleural margin:	0.8 cm.
Chest wall margin:	N/A.
Other margins:	N/A.
Pathologic tumor staging descriptors:	
Primary tumor (pT):	pT1b.
Regional lymph nodes (pN):	pN0.
Distant metastasis (pM):	N/A.
Margin status (R):	R0.
Pathologic stage:	IA.
Additional pathologic findings:	Focal organizing pneumonia and emphysematous changes.
Comment:	N/A.

[page 3 of 5]
Source of Specimen:

- A. N10R
- B. N10R#2
- C. N11R
- D. Lung;right upper lobe lung
- E. N4R
- F. N7

Clinical History/Operative Dx:

Right lung cancer

Intraoperative Diagnosis:

D. Right upper lobe lung (FSA): Bronchovascular margin is negative for carcinoma. The intraoperative interpretation(s) was/were performed and rendered at [REDACTED]

Gross Description:

A. The specimen is labeled N10R and is received in formalin. It consists of a 0.9 x 0.7 x 0.3 cm fragment of tan to anthracotic tissue. It is serially sectioned and entirely submitted in cassette A1. [REDACTED]

B. The specimen is labeled N10R#2 and is received in formalin. It consists of a 1 x 1 x 0.7 cm fragment of red-brown and anthracotic tissue. It is serially sectioned and entirely submitted in cassette B1. [REDACTED]

C. The specimen is labeled N11R and is received in formalin. It consists of a 0.7 x 0.6 x 0.4 cm fragment of anthracotic tissue. It is trisected and submitted in cassette C1. [REDACTED]

D. The specimen is labeled right upper lobe lung and is received without fixative. It consists of a lobe of lung with a fixed weight of 153 grams. It measures 12 cm from apex to base, 8 cm in width, and 4.5 cm from medial to lateral. The pleural surface generally has a brown-violet appearance and along the lateral apical surface of the lung, there is adherent fatty tissue. There is also a palpable mass in the lateral apical portion of the lung. A Y-shaped metallic staple line is present along the medial surface extending from the apex to the basilar portion. At the hilum, the bronchial and vascular margins are identified and removed for frozen section as FSA. There are three 0.2-0.8 cm anthracotic peribronchial nodes. The apical pleural surface with fatty involvement is inked. On sectioning of the apical portion of the lung, there is a sharply circumscribed, tan, centrally cavitory mass which measures 2.1 cm maximally. This mass is approximately 0.2 cm from the apical staple line of the specimen. It is 3 cm from the bronchial margin and approximately 5 cm from the interlobar staple line. Representative sections of the neoplasm are obtained for research purposes. This neoplasm is 0.8 cm from the closest pleural surface at the apical portion of the lung. Serial sections of the remainder of the lung reveal red-brown wet pulmonary

[page 4 of 5]
FINAL SURGICAL PATHOLOGY REPORT

parenchyma. 4 cm inferior to the apical neoplasm, along the lateral basilar portion of the lung, there is a subpleural 0.4 cm fibrous area. No other discrete palpable masses are present. Representative neoplasm is obtained for research purposes. Representative sections are submitted. Section summary:

- D1) bronchial and vascular margin from frozen section,
- D2) additional vascular margins,
- D3) peribronchial nodes,
- D4) apical staple line pulmonary parenchyma with closest approach of neoplasm,
- D5-D6) sections of neoplasm,
- D7) apical pleural surface at closest approach of neoplasm,
- D8) fibrotic pulmonary parenchyma just inferior to neoplasm,
- D9) small subpleural palpable mass lateral basilar portion of lung,
- D10) pulmonary parenchyma at interlobar staple line,
- D11) uninvolved lung [REDACTED]

E. The specimen is labeled N4R and is received in formalin. It consists of a 1.7 cm aggregate of fibrofatty and anthracotic tissue fragments. On gentle dissection five possible lymph nodes are identified which vary from 0.3-0.8 cm in maximum dimension. The two largest fragments are inked with contrasting colors. They are each bivalved and submitted in cassette E1. The remaining fragments are submitted intact in cassette E2. [REDACTED]

F. The specimen is labeled N7 and is received in formalin. It consists of six fragments of fibrofatty and anthracotic tissue which vary from 0.4 cm in maximum dimension to 1.4 x 0.6 x 0.6 cm. The two largest fragments are inked with contrasting colors. They are sectioned and submitted in cassette F1. The smaller fragments are submitted in cassette F2. [REDACTED]

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

C. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

D. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Immunohistochemistry was performed with adequate control for CK7, CK20, CK5/6, Napsin-A, OSCAR keratin, p63, and TTF-1. The tumor cells are positive for CK 5/6, p63 and CK7 (focal); and are negative for CK20, Napsin-A and TTF-1. OSCAR keratin shows no metastatic carcinoma in block D3 and D9.

E. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

F. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

[page 5 of 5]
FINAL SURGICAL PATHOLOGY REPORT

rendered.

Source: NCI Genomic Data Commons file ad0479b9-255d-4725-9f34-5fd7b61a5fa2 (TCGA-56-8628.E7266B19-B7FC-499B-9429-BA6AFCA960EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).